Somatic mutation profile of tumor specimen TCGA-DH-A7UU-01A (aliquot TCGA-DH-A7UU-01A-12D-A34A-08) from TCGA case TCGA-DH-A7UU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.9 years (16,037 days).
Specimen TCGA-DH-A7UU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a255d92-cb44-4907-b89e-7205d7f8c85c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A7UU-10A (Blood Derived Normal), aliquot TCGA-DH-A7UU-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/137773dc-4550-4a83-a53c-ff8a293b0665

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 50/109 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 34/98 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1554900534, CM110153, COSV100909234, COSV64301647, COSV64303094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99668520; called by muse, mutect2
- ACSF3 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1294989905, COSV100441236; called by muse, mutect2
- ACSL4 | c.2116C>T p.R706* (on ENST00000340800 / NM_022977.2; = p.R665* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100538476; called by muse, mutect2, varscan2
- ADCY8 | c.2936A>G p.D979G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99651727; called by muse, mutect2, varscan2
- AFP | c.1026T>A p.F342L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV99889907; called by muse, mutect2, varscan2
- AKR1B10 | c.450T>A p.D150E | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV100610174; called by muse, mutect2, varscan2
- B3GALT1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100002645; called by muse, mutect2, varscan2
- CAD | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776337242, COSV99254903; called by muse, mutect2, varscan2
- CLIC5 | c.744G>T p.E248D (on ENST00000185206 / NM_001370649.1; = p.E89D on NM_016929.5) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99484268; called by muse, mutect2, varscan2
- CPB1 | c.4T>A p.L2M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.642); catalogued as COSV99294195; called by muse, mutect2, varscan2
- HIVEP1 | c.1519G>C p.D507H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV101045069; called by muse, mutect2, varscan2
- IMPG2 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515325; called by muse, mutect2, varscan2
- KCNU1 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV101299136; called by muse, mutect2, varscan2
- KPRP | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100908691; called by muse, mutect2
- MLH3 | c.61T>G p.S21A | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99464978; called by muse, mutect2, varscan2
- MON2 | c.1116T>G p.F372L | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV54814497; called by muse, mutect2, varscan2
- MYO18B | c.2705T>C p.M902T | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100123348, COSV59144648; called by muse, mutect2, varscan2
- NOA1 | c.2013C>G p.I671M | Missense Mutation (SNP) | VAF 106/383 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99950489; called by muse, varscan2
- NOS3 | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as rs1312281138, COSV99871503; called by muse, mutect2, varscan2
- NUP160 | c.2710G>C p.V904L | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as COSV101021431; called by muse, mutect2, varscan2
- OGDHL | c.2711G>T p.S904I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100934273, COSV65104136; called by muse, mutect2, varscan2
- OR51T1 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100434379; called by muse, mutect2, varscan2
- OVCH1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771073063, COSV58964797; called by muse, mutect2, varscan2
- PRL | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV100122994; called by muse, mutect2
- RHOBTB3 | c.738C>G p.N246K | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101183174; called by muse, mutect2, varscan2
- ROR2 | c.949T>A p.Y317N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100995752; called by muse, mutect2, varscan2
- SLC6A2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557196282, COSV54921528; called by muse, mutect2, varscan2
- SPATA31D1 | c.837C>A p.C279* | Nonsense Mutation (SNP) | VAF 19/298 reads (6%) | catalogued as rs1366798789, COSV100782724; called by muse, mutect2
- TRPA1 | c.2555+2T>C p.X852_splice | Splice Site (SNP) | VAF 57/132 reads (43%) | catalogued as rs111533281, COSV100083856; called by muse, mutect2, varscan2
- YME1L1 | c.2315T>G p.V772G (on ENST00000326799 / NM_139312.3; = p.V715G on NM_014263.4) | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV100463541; called by muse, mutect2, varscan2
- ZNF81 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100095330, COSV100095548; called by muse, mutect2, varscan2
- C9orf152 | c.421_424del p.R141Afs*24 | Frame Shift Del (DEL) | VAF 24/145 reads (17%) | called by pindel*, varscan2
- VPS50 | c.1332_1333del p.S445Cfs*9 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel
- FAT1 | c.394C>A p.R132= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV101499290, COSV71671964; called by muse, mutect2, varscan2
- FRAS1 | c.10773A>G p.P3591= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99350754; called by muse, mutect2, varscan2
- GBP4 | c.384G>A p.S128= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs768351437, COSV63254759; called by muse, mutect2, varscan2
- HMBOX1 | c.552G>A p.R184= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV99816081; called by muse, mutect2
- HMCN1 | c.9537A>C p.P3179= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99627747; called by muse, mutect2, varscan2
- MOCS3 | c.111A>G p.E37= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as rs1267575574, COSV99724244; called by muse, mutect2, varscan2
- RBL2 | c.1374T>C p.A458= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100043556; called by muse, mutect2, varscan2
- TRIM56 | c.2139A>G p.G713= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100047219; called by muse, mutect2, varscan2
- WWC1 | c.2832G>T p.R944= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- ZP2 | c.1623C>A p.V541= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99559381; called by muse, mutect2, varscan2
